Somatic mutation profile of tumor specimen 0DUME7 from CCDI case PBCLLP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pineoblastoma; Tissue or organ of origin: Pineal gland; Age at diagnosis: 4.4 years (1,614 days).
Specimen 0DUME7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c0fe291-e6b8-4b22-af7f-7d34e692f33d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUMDQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e725b8e-7454-44fe-a6f7-3daae34c313a

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHFR | c.1375G>A p.D459N (on ENST00000432561 / NM_001161345.1; = p.D418N on NM_018223.2) | Missense Mutation (SNP) | VAF 96/230 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV57177434; called by muse, mutect2, varscan2
- AK5 | c.991G>T p.D331Y (on ENST00000354567 / NM_174858.3; = p.D305Y on NM_012093.4) | Missense Mutation (SNP) | VAF 299/615 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- BX276092.9 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 42/772 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- NHS | c.1826C>G p.S609C | Missense Mutation (SNP) | VAF 203/435 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TENM1 | c.2920C>A p.P974T | Missense Mutation (SNP) | VAF 144/314 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- FES | c.2050C>T p.L684= | Silent (SNP) | VAF 115/259 reads (44%) | called by muse, mutect2, varscan2
- H3C6 | c.21G>T p.T7= | Silent (SNP) | VAF 170/373 reads (46%) | catalogued as rs138589598; called by muse, mutect2, varscan2
- RBM10 | c.411A>G p.P137= | Silent (SNP) | VAF 64/184 reads (35%) | called by muse, varscan2
- USF3 | c.3408A>T p.A1136= | Silent (SNP) | VAF 16/422 reads (4%) | catalogued as COSV57072566; called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 11/157 reads (7%) | called by muse, mutect2
- LRFN4 | c.*5C>T | 3'UTR (SNP) | VAF 94/180 reads (52%) | catalogued as rs753005646; called by muse, mutect2, varscan2
